Somatic mutation profile of tumor specimen TCGA-XN-A8T5-01A (aliquot TCGA-XN-A8T5-01A-12D-A36O-08) from TCGA case TCGA-XN-A8T5, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Head of pancreas; AJCC pathologic stage: Stage IB; Tumor grade: G2; Age at diagnosis: 54.0 years (19,707 days).
Specimen TCGA-XN-A8T5-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d25a70bc-9107-43d2-bd4b-584c04ecb281.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-XN-A8T5-10A (Blood Derived Normal), aliquot TCGA-XN-A8T5-10A-01D-A367-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6c4ee6a7-82fd-4d65-90e4-7eab09da66bc

The open-access MAF lists 14 somatic variants for this specimen: 8 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 8, Silent 6.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CD1D | c.656G>A p.R219H | Missense Mutation (SNP) | VAF 32/545 reads (6%) | SIFT tolerated (0.47); PolyPhen benign (0.03); catalogued as rs199860570, COSV63809742; called by muse, mutect2
- GABRQ | c.1211C>T p.A404V | Missense Mutation (SNP) | VAF 23/424 reads (5%) | SIFT tolerated (0.38); PolyPhen benign (0.042); catalogued as rs1210470171, COSV100941412; called by muse, mutect2
- GPC5 | c.271A>G p.T91A | Missense Mutation (SNP) | VAF 26/468 reads (6%) | SIFT tolerated (0.38); PolyPhen benign (0.086); catalogued as COSV100995577; called by muse, mutect2
- NCKIPSD | c.1660T>A p.C554S | Missense Mutation (SNP) | VAF 10/224 reads (4%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.636); catalogued as COSV99584207; called by muse, mutect2
- PANK3 | c.184G>A p.G62S | Missense Mutation (SNP) | VAF 42/728 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs970466941, COSV99496562; called by muse, mutect2
- PLXNB2 | c.3280G>T p.D1094Y | Missense Mutation (SNP) | VAF 13/286 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV63782623; called by muse, mutect2
- BICC1 | c.1801C>T p.P601S | Missense Mutation (SNP) | VAF 11/230 reads (5%) | SIFT tolerated (0.22); PolyPhen benign (0.003); called by muse, mutect2
- ITPR1 | c.4528G>T p.V1510L (on ENST00000354582; = p.V1495L on NM_002222.7) | Missense Mutation (SNP) | VAF 8/162 reads (5%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.995); called by muse, mutect2
- ANKRD35 | c.2916C>T p.Y972= | Silent (SNP) | VAF 26/545 reads (5%) | catalogued as rs1553738004, COSV100841836; called by muse, mutect2
- ARHGAP15 | c.1293G>T p.G431= | Silent (SNP) | VAF 21/646 reads (3%) | catalogued as COSV99713069; called by muse, mutect2
- BDP1 | c.2983A>C p.R995= | Silent (SNP) | VAF 19/437 reads (4%) | catalogued as rs1341611331, COSV100703452; called by muse, mutect2
- RNF13 | c.153C>T p.L51= | Silent (SNP) | VAF 14/250 reads (6%) | catalogued as COSV100712748; called by muse, mutect2
- ZBED4 | c.1335C>T p.A445= | Silent (SNP) | VAF 49/486 reads (10%) | catalogued as rs141708563; called by muse, mutect2, varscan2
- ZNF614 | c.748C>T p.L250= | Silent (SNP) | VAF 17/620 reads (3%) | called by muse, mutect2
